Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A212, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A212-01A (Primary Tumor).

[page 1 of 8]
ICD-0-3
Adenocarcinoma, serous, papillary 8460/3
Site: Endometrium c54.1 lw 4/8/11

SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Uterus and cervix, radical hysterectomy and bilateral salpingo-oophorectomy:

Location of tumor: Anterior and posterior endometrium

Histologic type: Papillary serous adenocarcinoma with clear cell features (5%) A14) ✓

Histologic grade (FIGO): FIGO grade 3 ✓

Extent of invasion:

Myometrial invasion: Inner half

Depth: 0.5 cm Wall thickness: 1.1 cm Percent: 45% (A15)

Serosal involvement: Not involved

Lower uterine segment involvement: Involved, anterior and posterior (e.g. A10)

Cervical involvement: Focal tumor invades the superficial cervical stroma to 1 mm in depth out of 1.1 cm in cervical wall thickness, extending to 4 mm from the ectocervical/ vaginal cuff margin (A5)

Adnexal involvement (see below): Focal microscopic involvement of the left ovary present (A3)

Other sites: None

Cervical/vaginal margin and distance: Tumor extends to 0.4 cm from the cauterized cervical margin (A5)

Lymphovascular Space Invasion: Present (A7)

Regional lymph nodes (see other specimens):
Total number involved: 1 (E5) (see comment)
Total number examined: 52

Revised: RMT	Date Reviewed: lw 4/8/11	

[page 2 of 8]
Other Pathologic findings:

- Adenomyosis
- Calcification of vessel walls
- Hemangioma of endocervix

Tumor estrogen receptor and progesterone receptor immunohistochemistry results:
pending; final results will be issued in an addendum report (A15)

Tumor is MSH2 positive (2-3+, 30%), MSH6 positive (2-3+, 30%), and MLH1 positive (2+, 25%) (A15), by immunohistochemistry.

Tumor tissue is submitted to molecular pathology for molecular assay for microsatellite instability (A15); please see molecular pathology report for final results.

AJCC Pathologic stage: pT3c pN1 pMX
FIGO (2008 classification) Stage grouping: IIIC1)

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Ovary, right, oophorectomy:
-Surface inclusion cysts with tubal metaplasia
-No evidence of malignancy

Ovary, left, oophorectomy:
-Focal micrometastatic adenocarcinoma involves ovarian cortex, <0.1 mm in size (A3)
-Surface inclusion cysts

Fallopian tube, right, salpingectomy:
-Not identified grossly or microscopically

Fallopian tube, left, salpingectomy:
-Benign paratubal cysts
-No evidence of malignancy (floaters present)

B: Lymph node, right para-aortic, removal

[page 3 of 8]
-No metastatic carcinoma identified in thirteen lymph nodes (0/13)

C: Lymph node, left para-aortic, removal

-No metastatic carcinoma identified in six lymph nodes (0/6)

D: Lymph node, right pelvic, removal

-No metastatic carcinoma identified in seventeen lymph nodes (0/17)

E: Lymph node, left pelvic, removal

-One out of 16 lymph nodes shows focal metastatic adenocarcinoma, 0.7 mm in size, confirmed by immunohistochemical stain for pancytokeratin (1/16)

COMMENT:

Immunostains for pancytokeratin (AE1/AE3) are performed on several lymph nodes to rule out micrometastases (E5, E1, E2, and D7). Focal micrometastatic adenocarcinoma is noted in one node in block E5 (the rest of the immunostains show no evidence of metastatic carcinoma).

Clinical History:

-year-old female with endometrial cancer.

Gross Description:

Received are five appropriately labeled containers.

Container A is additionally labeled "uterus, cervix, B tubes and ovaries."

Adnexa: present on the specimen bilaterally

Weight: 84.5 grams

Shape: pear shaped

Dimensions:

height: 8.0 cm

anterior to posterior width: 3.0 cm

breadth at fundus: 5.7 cm

Serosa: tan/pink and smooth with no focal lesions

Cervix:

length of endocervical canal: 2.2 cm

[page 4 of 8]
ectocervix: pink/tan mucosa with punctate hemorrhages
endocervix: pink/tan, trabeculated mucosa; no definite lesions
Endomyometrium:

length of endometrial cavity: 4.5 cm

width of endometrial cavity at fundus: 3.3 cm

tumor findings:

dimensions: 3.4 x 2.4 x 0.8 cm (exophytic component)

appearance: tan/pink, friable, exophytic lesion

location and extent: tumor involves both the anterior and posterior

upper corpus, anterior mid corpus, and suspicious for involvement of posterior mid corpus

myometrial invasion: Grossly, invasion into the inner half of the myometrium.

thickness of myometrial wall at deepest gross invasion: 1.2 cm (anterior mid corpus)

other findings or comments: none

Adnexa:

Right ovary:

dimensions: 1.5 x 0.6 x 0.3 cm

external surface: yellow/tan and minimally lobulated

cut surface: yellow/tan; no grossly identified lesions

Right fallopian tube: Not identified grossly; the right meso-ovarian is

serially sectioned and no fallopian tube candidate is identified.

Left ovary:

dimensions: 1.0 x 0.7 x 0.4 cm

external surface: yellow/tan with minimal lobulations

cut surface: yellow/tan, grossly normal

Left fallopian tube:

dimensions: 5.2 cm in length x 0.5 cm in diameter

other findings: The external surface is purple/tan with no gross abnormalities.

Lymph nodes: see Specimens B-E

Other comments: none

Digital photograph taken: no

[page 5 of 8]
Tissue submitted for special investigations: Representative tumor is provided to Tissue Procurement.

Block Summary:

- A1 - right ovary
- A2 - right meso-ovarian/?right fallopian tube
- A3 - left ovary
- A4 - left fallopian tube
- A5 - anterior cervix and endocervical canal, perpendicular sections
- A6 - anterior lower uterine segment
- A7 - anterior mid corpus, full thickness section, greatest depth of invasion?
- A8 - anterior mid corpus, full thickness section
- A9 - anterior upper corpus/fundus, full thickness section
- A10 - posterior cervix and endocervical canal, perpendicular section
- A11 - posterior lower uterine segment, full thickness section
- A12 - posterior lower uterine segment, full thickness section
- A13 - posterior mid corpus, full thickness section
- A14 - posterior upper corpus, full thickness section
- A15 - posterior upper corpus, full thickness section

Container B is additionally labeled "R para-aortic lymph node." The specimen consists of a portion of yellow/brown fibroadipose tissue measuring 5.3 x 3.3 x 0.8 cm in aggregate. Ten lymph node candidates measuring 0.1-0.9 cm in greatest dimension are identified.

Block summary:

- B1 - three lymph node candidates
- B2 - four lymph node candidates
- B3 - three lymph node candidates
- B4-B7 - remaining fibroadipose tissue,

Container C is additionally labeled ". The specimen consists of multiple small fragments of yellow/brown

[page 6 of 8]
fibroadipose tissue
measuring 2.9 x 1.5 x 0.4 cm in aggregate. The specimen is
palpated to reveal
five lymph node candidates measuring 0.1 0.4 cm in greatest
dimension.

Block summary:

C1 - two lymph node candidates, (one blue inked lymph node
candidate
bisected)
C2 - three lymph node candidates
C3,C4 - remaining fibroadipose tissue,

Container D is additionally labeled the specimen
consists of
multiple fragments of yellow/brown fibroadipose tissue measuring
7.1 x 4.3 x 0.8
cm in aggregate. The specimen is palpated to reveal 16 lymph
node candidates
measuring 0.1 4.0 cm in greatest dimension.

Block summary:

D1 - two lymph node candidates
D2 - four lymph node candidates
D3 - three lymph node candidates (one black inked lymph node
candidate
bivalved)
D4 - two lymph node candidates, each bivalved (one inked black)
D5 - two lymph node candidates, each bivalved (one lymph node
candidate
inked black)
D6 - one lymph node candidate, serially sectioned
D7,D8 - one lymph node candidate, serially sectioned
D9-D12 - largest lymph node candidate, serially sectioned
D13-D17- remaining fibroadipose tissue,

Container E is additionally labeled " " The specimen
consists of a
portion of yellow/brown fibroadipose tissue measuring 7.3 x 4.8
x 1.0 cm in
aggregate. Palpation of the specimen yields 15 lymph node
candidates measuring
0.1 4.7 cm in greatest dimension.

Block summary:

[page 7 of 8]
E1 - five lymph node candidates
E2 - three lymph node candidates
E3 - three lymph node candidates (black inked lymph node candidate bivalved)

E4 - two lymph node candidates, each bivalved (one inked black)
E5,E6 - one lymph node candidate, serially sectioned
E7-E10 - largest lymph node candidate, serially sectioned
E11-E14 - remaining fibroadipose tissue,

Grossing Pathologist:, MD

Light Microscopy:

Light microscopic examination is performed by Dr.

Signature

Resident Physician:, MD

Attending Pathologist:, MD

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Electronically Signed by:

, MD

Date

Procedures/Addenda:

Addendum

Addendum

Immunostains for ER and PR are performed on a representative block of endometrial tumor (A15). The tumor is ER positive (2+, 15%) and PR positive (2+, 20%).

Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR) or research use only (RUO) reagents. These were developed and have performance characteristics determined by the

[page 8 of 8]
. These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Electronically Signed: ,MD Date:

Source: NCI Genomic Data Commons file 21e2e733-be24-4633-bd60-80b058d875aa (TCGA-EY-A212.3E8012E3-97F1-48A2-B1C0-5C814DF8EE01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).